Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6530, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6530-01A (Primary Tumor).

[page 1 of 2]
TCGA – D5 – 6530

page 1 / 1

Department of Cancer Pathology

Examination: Histopathological examination

Material: 1. Multiple organ resection – cancer of the caecum – right half of the colon with the distal part of the ileum

Physician in charge:

Material collected on Material received on:

Expected time of examination:

Clinical diagnosis: Cancer of the caecum – right half of the colon with the distal part of the ileum

Examination performed on

Macroscopic description:

30 cm length of the large intestine with a fragment of the mesentery sized 17 x 19 x 5 cm, a 9 cm segment of the small intestine, and the appendix of 6 cm in length. Cauliflower-shaped, ulcerous tumour in the mucosa sized 4.5 x 4 x 1 cm. The lesion surrounds 100% of the intestine circumference and narrows its lumen, is situated 12 cm from the proximal cut line and 20 cm from the distal cut line. The lesion macroscopically invades through the periintestinal tissue. Minimum side margin is 4 cm.

Microscopic description:

Adenocarcinoma tubulare (G2). Infiltratio carcinomatosa tunicae muscularis propriae.

Intestine ends free of neoplastic lesions.

Lymphonodulitis reactiva No XV.

Examination result:

Adenocarcinoma tubulare coli. Tubular adenocarcinoma of the colon (G2, Dukes A, Astler - Coller B1, pT2, pN0).

[page 2 of 2]
Histopathological diagnosis:

Adenocarcinoma mucocellulare partim tubulare et mucinosum invasivum ventriculi. Mucocellular and partially tubular and mucinous invasive adenocarcinoma of the stomach.

Metastases carcinomatosae in lymphonodorum (No XVII/XX). Cancer metastases of the lymph nodes (No XVII/XX)

(G3, pT2, pN3)

Source: NCI Genomic Data Commons file 19fef4ef-5f14-40a8-b743-498aec03574a (TCGA-D5-6530.5A7B76ED-D0D1-45A6-814C-3DFFB6F4B717.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).